Somatic mutation profile of tumor specimen ALCH-B2A4-TTR1-A (aliquot ALCH-B2A4-TTR1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B2A4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 73.2 years (26,750 days).
Specimen ALCH-B2A4-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1472be76-bbba-471f-9dd1-54b1730432d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2A4-NB1-A (Blood Derived Normal), aliquot ALCH-B2A4-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/828bbf7b-3053-4fd1-929a-060a211429df

The open-access MAF lists 336 somatic variants for this specimen: 234 protein-altering or splice-affecting, 68 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 189, Silent 68, Nonsense Mutation 26, Intron 16, Frame Shift Del 10, RNA 6, Splice Site 5, 5'UTR 5, 3'UTR 4, 5'Flank 3, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNOT9 | c.259T>C p.S87P | Missense Mutation (SNP) | VAF 130/517 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1057519956, COSV55299564; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 176/263 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 196/406 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ORC6 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs777153067; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.3803G>A p.R1268Q | Missense Mutation (SNP) | VAF 134/265 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72549394, CM980252, COSV55593121; called by muse, mutect2, varscan2
- AC136428.1 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 123/244 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV71169188; called by muse, mutect2, varscan2
- ADGRB3 | c.1897G>T p.A633S | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as rs921122129; called by muse, mutect2, varscan2
- AMY1C | c.1064C>A p.S355* | Nonsense Mutation (SNP) | VAF 57/620 reads (9%) | catalogued as rs750733489; called by muse, varscan2
- ANHX | c.793C>G p.P265A | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as COSV69293955; called by muse, mutect2, varscan2
- ARHGAP5 | c.4363G>A p.V1455I (on ENST00000345122 / NM_001030055.2; = p.V1454I on NM_001173.3) | Missense Mutation (SNP) | VAF 147/381 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1203882701; called by muse, mutect2, varscan2
- BOD1L2 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.283); catalogued as COSV101649286; called by muse, mutect2, varscan2
- C2CD3 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs754367795, COSV58090296, COSV58097566; called by muse, mutect2, varscan2
- C8B | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 312/416 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557740342, COSV64777353; called by muse, mutect2, varscan2
- CACNA2D4 | c.2191G>T p.V731L | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV54948398; called by muse, mutect2, varscan2
- CBFA2T3 | c.1616C>G p.S539C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV51931195; called by muse, mutect2, varscan2
- CCDC39 | c.2735C>T p.P912L | Missense Mutation (SNP) | VAF 109/158 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as rs760435440; called by muse, mutect2, varscan2
- CDYL2 | c.1223A>G p.N408S | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.521); catalogued as rs753801497; called by muse, mutect2, varscan2
- CEP290 | c.5722G>T p.E1908* | Nonsense Mutation (SNP) | VAF 73/137 reads (53%) | catalogued as CM072937, COSV58355803; called by muse, mutect2, varscan2
- CHP1 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100587019; called by muse, varscan2
- CLEC4C | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 101/279 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV63582527; called by muse, mutect2, varscan2
- CNGB3 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 276/488 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs139207764, CM154647, COSV100181056; ClinVar: uncertain significance / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2
- COL1A1 | c.3314G>T p.R1105I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CD063482; called by muse, mutect2, varscan2
- COL6A2 | c.1531G>A p.G511S | Missense Mutation (SNP) | VAF 107/289 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs727502833, COSV100153766; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CP | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 91/117 reads (78%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.595); catalogued as COSV52832012, COSV52834146; called by muse, mutect2, varscan2
- CSMD2 | c.8434C>T p.R2812C | Missense Mutation (SNP) | VAF 65/90 reads (72%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1398421781; called by muse, mutect2, varscan2
- DCAF4L2 | c.59G>T p.R20I | Missense Mutation (SNP) | VAF 141/241 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60479766, COSV60481411; called by muse, mutect2, varscan2
- DCHS1 | c.9757A>T p.S3253C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54998279; called by muse, mutect2, varscan2
- DLL4 | c.1405G>T p.G469C | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99989742; called by muse, mutect2, varscan2
- DNAH8 | c.10057G>T p.A3353S | Missense Mutation (SNP) | VAF 113/263 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59444496; called by muse, mutect2, varscan2
- DUXA | c.261G>T p.Q87H | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV73729670; called by muse, mutect2, varscan2
- DYNC1H1 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 26/545 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64143104; called by muse, mutect2
- FAM171A1 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 145/354 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.897); catalogued as rs762827738, COSV65317711; called by muse, mutect2, varscan2
- FAM71B | c.331C>A p.R111S | Missense Mutation (SNP) | VAF 116/297 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV57228351; called by muse, mutect2, varscan2
- GABRB3 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 273/655 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV54659758, COSV54677069; called by muse, mutect2, varscan2
- GPA33 | c.691+1G>T p.X231_splice | Splice Site (SNP) | VAF 67/127 reads (53%) | catalogued as COSV63300760; called by muse, mutect2, varscan2
- GPR155 | c.2473C>T p.R825W | Missense Mutation (SNP) | VAF 125/344 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs528682867, COSV55039349; called by muse, mutect2, varscan2
- HMMR | c.275G>C p.R92P | Missense Mutation (SNP) | VAF 121/323 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62375180; called by muse, mutect2, varscan2
- IGFALS | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs561329938, COSV51905092; called by muse, mutect2, varscan2
- IGLV2-14 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 107/276 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.246); catalogued as rs768131871; called by muse, mutect2, varscan2
- IL31RA | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 171/482 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as COSV51680542; called by muse, mutect2, varscan2
- KALRN | c.7117G>A p.E2373K (on ENST00000360013 / NM_001024660.4; = p.E676K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749778361; called by muse, mutect2, varscan2
- KEAP1 | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 183/219 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50261740; called by muse, mutect2, varscan2
- LILRB1 | c.1478G>T p.G493V | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV61121187; called by muse, mutect2, varscan2
- MALRD1 | c.3307C>G p.P1103A | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.506); catalogued as COSV101039633; called by muse, mutect2, varscan2
- MAP7D3 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 90/110 reads (82%) | SIFT tolerated (0.28); PolyPhen benign (0.109); catalogued as rs1312380475; called by muse, mutect2, varscan2
- MROH2A | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 97/409 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.588); catalogued as rs1287521749; called by muse, mutect2, varscan2
- MROH7 | c.461A>T p.K154M | Missense Mutation (SNP) | VAF 74/113 reads (65%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.178); catalogued as rs375822785; called by muse, mutect2, varscan2
- NPAP1 | c.2959G>T p.G987W | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV100274795; called by muse, mutect2, varscan2
- NR4A1 | c.894C>A p.N298K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.21); catalogued as COSV54482935; called by muse, mutect2
- NRCAM | c.385C>A p.R129S (on ENST00000379028 / NM_001371124.1; = p.R123S on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.664); catalogued as COSV61044271; called by muse, mutect2, varscan2
- NUP153 | c.2384G>T p.G795V | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs778385534; called by muse, mutect2, varscan2
- NUP205 | c.4146G>T p.E1382D | Missense Mutation (SNP) | VAF 60/472 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as COSV53655593; called by muse, mutect2, varscan2
- OR4C15 | c.671C>T p.P224L (on ENST00000314644; = p.P170L on NM_001001920.2) | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs756094344, COSV58953119; called by muse, mutect2, varscan2
- PAQR6 | c.553del p.R185Afs*35 (on ENST00000292291 / NM_001272108.2; = p.R79Afs*35 on NM_024897.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 205/305 reads (67%) | catalogued as rs763189895, COSV99430646; called by mutect2, pindel, varscan2
- PCDHGB1 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV53910531; called by muse, mutect2, varscan2
- PEG3 | c.1743C>G p.H581Q | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs771837389; called by muse, mutect2, varscan2
- PF4V1 | c.160C>G p.R54G | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV104389561; called by muse, mutect2, varscan2
- PJA1 | c.1301del p.G434Afs*50 (on ENST00000361478 / NM_145119.4; = p.G246Afs*50 on NM_022368.5) | Frame Shift Del (DEL) | VAF 68/96 reads (71%) | catalogued as COSV64053553; called by mutect2, pindel*, varscan2
- PLCL1 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 72/202 reads (36%) | catalogued as COSV70820741; called by muse, mutect2
- POSTN | c.1465del p.R489Afs*15 | Frame Shift Del (DEL) | VAF 120/392 reads (31%) | catalogued as COSV65712393; called by pindel, varscan2
- SIGLEC14 | c.587C>A p.S196* | Nonsense Mutation (SNP) | VAF 74/139 reads (53%) | catalogued as rs1474872460, COSV55778812; called by muse, mutect2
- SLC17A6 | c.923C>A p.T308K | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99581952; called by muse, mutect2, varscan2
- SLC26A7 | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 112/395 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as COSV99404630; called by muse, mutect2, varscan2
- SLC28A2 | c.1489C>T p.Q497* | Nonsense Mutation (SNP) | VAF 179/469 reads (38%) | catalogued as rs988688425; called by muse, mutect2, varscan2
- SMARCA4 | c.1636A>T p.K546* | Nonsense Mutation (SNP) | VAF 365/436 reads (84%) | catalogued as CD122496; called by muse, mutect2, varscan2
- SOX11 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1252447458; called by muse, mutect2, varscan2
- TACC2 | c.7154C>T p.S2385F (on ENST00000334433; = p.S463F on NM_006997.4) | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763304795, COSV53279843; called by muse, mutect2, varscan2
- THEMIS | c.1697C>G p.T566R | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV64072673; called by muse, mutect2, varscan2
- TNR | c.4058G>A p.R1353Q | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs779239538, COSV54904244; called by muse, mutect2, varscan2
- TRPM3 | c.287G>T p.G96V (on ENST00000357533 / NM_001366142.2; = p.G65V on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.184); catalogued as COSV100624545; called by muse, varscan2
- UGT2B28 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV59432192; called by muse, mutect2, varscan2
- XIRP2 | c.8753G>T p.R2918L (on ENST00000628543; = p.R3093L on NM_152381.6) | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV54679955; called by muse, mutect2, varscan2
- ZNF292 | c.2506G>T p.E836* | Nonsense Mutation (SNP) | VAF 80/203 reads (39%) | catalogued as COSV60544633; called by muse, mutect2, varscan2
- ACCS | c.806T>A p.L269Q | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAD1 | c.417C>A p.Y139* | Nonsense Mutation (SNP) | VAF 57/165 reads (35%) | called by muse, mutect2, varscan2
- ADAM33 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM33 | c.1771G>C p.V591L | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ADAMTS2 | c.912C>A p.D304E | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ADAMTS20 | c.3254G>T p.W1085L | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- ADD2 | c.744C>A p.H248Q | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ADGRL3 | c.3157C>G p.L1053V (on ENST00000506720 / NM_001322402.2; = p.L985V on NM_015236.6) | Missense Mutation (SNP) | VAF 111/315 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- ADGRL3 | c.3823G>A p.A1275T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ADGRV1 | c.3965A>G p.H1322R | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ALDOC | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 98/219 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ASB4 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- ATP6V0A1 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- BCL11B | c.2472C>A p.Y824* (on ENST00000357195 / NM_001282237.2; = p.Y753* on NM_022898.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 111/276 reads (40%) | called by muse, mutect2, varscan2
- BMS1 | c.756_757del p.H253Pfs*24 | Frame Shift Del (DEL) | VAF 76/254 reads (30%) | called by pindel, varscan2
- BOD1L1 | c.5378G>T p.S1793I | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C11orf53 | c.752G>C p.G251A | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C8orf34 | c.1226G>A p.C409Y | Missense Mutation (SNP) | VAF 107/351 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1C | c.6581C>A p.P2194Q (on ENST00000399634 / NM_001167625.1; = p.P2123Q on NM_000719.7) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1I | c.5066G>T p.R1689L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CACNG6 | c.467G>T p.C156F | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- CADM2 | c.654G>C p.M218I (on ENST00000407528 / NM_001167674.2; = p.M220I on NM_153184.4) | Missense Mutation (SNP) | VAF 55/84 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CALCR | c.347del p.G116Vfs*27 | Frame Shift Del (DEL) | VAF 49/167 reads (29%) | called by mutect2, pindel, varscan2
- CCDC168 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CCNB3 | c.3530T>C p.M1177T | Missense Mutation (SNP) | VAF 84/111 reads (76%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CNTN1 | c.2203C>A p.H735N | Missense Mutation (SNP) | VAF 86/243 reads (35%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CPPED1 | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRB1 | c.10A>T p.K4* | Nonsense Mutation (SNP) | VAF 163/569 reads (29%) | called by muse, mutect2, varscan2
- CSPG5 | c.1659G>C p.Q553H (on ENST00000383738 / NM_001206943.2; = p.Q526H on NM_006574.4) | Missense Mutation (SNP) | VAF 83/116 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CUBN | c.9604A>T p.N3202Y | Missense Mutation (SNP) | VAF 151/401 reads (38%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- DNAJC12 | c.78+2T>A p.X26_splice | Splice Site (SNP) | VAF 38/95 reads (40%) | called by muse, mutect2, varscan2
- DNMT3A | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- DRC1 | c.779A>T p.N260I | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSG3 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 61/78 reads (78%) | called by muse, mutect2, varscan2
- EMSY | c.2597A>T p.Q866L | Missense Mutation (SNP) | VAF 185/404 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ETFB | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 124/306 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- FAM98A | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 92/180 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBN2 | c.6920C>A p.S2307Y | Missense Mutation (SNP) | VAF 226/544 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FSIP2 | c.19528C>G p.Q6510E | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- GHR | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 206/550 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GPR158 | c.1828C>G p.P610A | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GUCY1A1 | c.826del p.V276* | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | called by mutect2, pindel, varscan2
- HAS2 | c.1524dup p.Q509Tfs*28 | Frame Shift Ins (INS) | VAF 63/310 reads (20%) | called by mutect2, pindel, varscan2
- IGKV2D-28 | c.188A>T p.Q63L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.337); called by mutect2, varscan2
- ITIH5 | c.2803G>T p.G935C | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KMT2B | c.2862_2866del p.H956Rfs*37 | Frame Shift Del (DEL) | VAF 59/150 reads (39%) | called by mutect2, pindel, varscan2
- KRT35 | c.1160G>T p.R387L | Missense Mutation (SNP) | VAF 107/246 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- KRTAP10-3 | c.284G>A p.C95Y | Missense Mutation (SNP) | VAF 155/434 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMA2 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 127/332 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LDLRAD1 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 81/113 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LEF1 | c.55G>C p.A19P | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LHX8 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 58/78 reads (74%) | SIFT tolerated (0.19); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- LRFN5 | c.562A>T p.K188* | Nonsense Mutation (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- LRRCC1 | c.543A>T p.P181= | Splice Region (SNP) | VAF 112/218 reads (51%) | called by muse, mutect2, varscan2
- LUZP4 | c.153del p.R51Sfs*56 | Frame Shift Del (DEL) | VAF 76/127 reads (60%) | called by mutect2, pindel, varscan2
- MAGEB5 | c.223C>A p.Q75K | Missense Mutation (SNP) | VAF 73/96 reads (76%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAP2K1 | c.517-1G>T p.X173_splice | Splice Site (SNP) | VAF 184/488 reads (38%) | called by muse, mutect2, varscan2
- MAP3K9 | c.707G>T p.R236M | Missense Mutation (SNP) | VAF 88/254 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- MLLT6 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPPED2 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTHFD2 | c.992T>A p.V331E | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- MTUS2 | c.2291T>A p.M764K | Missense Mutation (SNP) | VAF 168/460 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- MUC2 | c.2750C>A p.S917Y | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MUC5B | c.1301C>A p.S434Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- MYBL2 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 38/101 reads (38%) | called by muse, mutect2, varscan2
- MYBPC1 | c.3171T>G p.Y1057* (on ENST00000550270 / NM_206820.2; = p.Y1064* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 115/341 reads (34%) | called by muse, mutect2, varscan2
- MYH2 | c.4390C>T p.Q1464* | Nonsense Mutation (SNP) | VAF 142/313 reads (45%) | called by muse, mutect2, varscan2
- NEDD1 | c.1682_1684del p.A561del | In Frame Del (DEL) | VAF 58/154 reads (38%) | called by pindel, varscan2
- NEDD4 | c.3890C>T p.S1297L (on ENST00000508342 / NM_001284338.1; = p.S878L on NM_006154.4) | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NFKB1 | c.1242T>A p.Y414* (on ENST00000394820 / NM_001382627.1; = p.Y415* on NM_003998.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- NLRP7 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 148/401 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPTX2 | c.723G>T p.K241N | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- NUP133 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2
- OPN3 | c.52del p.A18Pfs*13 | Frame Shift Del (DEL) | VAF 18/33 reads (55%) | called by mutect2, pindel, varscan2
- OR2H2 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2L3 | c.332C>A p.A111E | Missense Mutation (SNP) | VAF 309/628 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- PARG | c.2283C>G p.I761M | Missense Mutation (SNP) | VAF 72/271 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PATJ | c.3935C>G p.S1312* | Nonsense Mutation (SNP) | VAF 42/60 reads (70%) | called by muse, mutect2
- PCDHA1 | c.2188G>T p.G730C | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2
- PCDHGA6 | c.1785_1786del p.D595Efs*170 | Frame Shift Del (DEL) | VAF 72/236 reads (31%) | called by mutect2, pindel, varscan2
- PCLO | c.14368A>T p.T4790S | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- PDHB | c.728C>A p.S243* | Nonsense Mutation (SNP) | VAF 12/246 reads (5%) | called by muse, mutect2
- PDP2 | c.1005G>T p.E335D | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF3 | c.1893G>T p.Q631H | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCB4 | c.206G>C p.R69P | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PLCL1 | c.554G>T p.C185F | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2
- PLEKHO1 | c.563A>G p.D188G | Missense Mutation (SNP) | VAF 42/45 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PNMA8B | c.224A>T p.H75L | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PNPLA5 | c.834G>T p.W278C | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- POLE | c.1991A>T p.Q664L | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- PPFIBP1 | c.1998T>A p.N666K (on ENST00000318304 / NM_177444.3; = p.N660K on NM_003622.4) | Missense Mutation (SNP) | VAF 114/312 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- PPFIBP1 | c.1999T>A p.S667T (on ENST00000318304 / NM_177444.3; = p.S661T on NM_003622.4) | Missense Mutation (SNP) | VAF 113/310 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PPP1R16B | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PPP1R26 | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 59/79 reads (75%) | SIFT tolerated (0.11); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- PRAMEF15 | c.654G>T p.W218C | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PRR36 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 115/133 reads (86%) | SIFT tolerated, low confidence (0.69); called by muse, mutect2, varscan2
- PSMB11 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 37/110 reads (34%) | called by muse, mutect2, varscan2
- PSMD13 | c.464T>A p.F155Y | Missense Mutation (SNP) | VAF 77/211 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PTH2R | c.1363G>T p.V455L | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTK2 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 99/365 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- PTPRN2 | c.3013G>T p.E1005* | Nonsense Mutation (SNP) | VAF 65/136 reads (48%) | called by muse, mutect2, varscan2
- QSOX1 | c.954G>T p.R318S | Missense Mutation (SNP) | VAF 203/225 reads (90%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAI14 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- RELN | c.3144C>A p.C1048* | Nonsense Mutation (SNP) | VAF 163/436 reads (37%) | called by muse, mutect2, varscan2
- RESP18 | c.290C>A p.P97Q | Missense Mutation (SNP) | VAF 116/219 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RNF17 | c.4545T>A p.F1515L | Missense Mutation (SNP) | VAF 86/217 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RTKN | c.590G>T p.G197V (on ENST00000272430 / NM_001015055.2; = p.G184V on NM_033046.2) | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SCN3A | c.2848G>T p.D950Y | Missense Mutation (SNP) | VAF 185/513 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHANK3 | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHISAL1 | c.230A>T p.Q77L | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SIN3A | c.1634A>T p.E545V | Missense Mutation (SNP) | VAF 154/400 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC13A1 | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- SLC25A13 | c.1964G>T p.G655V | Missense Mutation (SNP) | VAF 109/330 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLC35G3 | c.125T>G p.V42G | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- SLC6A16 | c.1426G>T p.G476C | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A16 | c.1425G>T p.E475D | Missense Mutation (SNP) | VAF 89/187 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SLC7A10 | c.660C>A p.S220R | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMG9 | c.757A>T p.T253S | Missense Mutation (SNP) | VAF 130/354 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- SNAP25 | c.592C>A p.R198S | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SPANXN2 | c.50G>T p.C17F | Missense Mutation (SNP) | VAF 96/132 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPRED1 | c.163T>A p.C55S | Missense Mutation (SNP) | VAF 132/394 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTA1 | c.86A>T p.Q29L | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- STAB2 | c.1735G>T p.G579* | Nonsense Mutation (SNP) | VAF 110/311 reads (35%) | called by muse, mutect2, varscan2
- STIM2 | c.1958G>T p.C653F | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- STXBP2 | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 244/285 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- STXBP2 | c.664-2A>T p.X222_splice | Splice Site (SNP) | VAF 161/180 reads (89%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.1181G>T p.R394M | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SYT16 | c.1802T>A p.M601K | Missense Mutation (SNP) | VAF 170/431 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SYT9 | c.1293C>A p.N431K | Missense Mutation (SNP) | VAF 109/222 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- TAF1L | c.4978C>A p.P1660T | Missense Mutation (SNP) | VAF 114/148 reads (77%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.993); called by muse, varscan2
- THBS2 | c.2140C>A p.H714N | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TLR10 | c.620T>G p.L207W | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- TMEM200A | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 81/260 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM59 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 81/128 reads (63%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- TPP1 | c.1532A>G p.H511R | Missense Mutation (SNP) | VAF 100/267 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAV22 | c.52+1G>T p.X18_splice | Splice Site (SNP) | VAF 96/199 reads (48%) | called by muse, mutect2, varscan2
- TRGJP | c.44C>G p.T15R | Missense Mutation (SNP) | VAF 72/244 reads (30%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM21 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRPM3 | c.286G>C p.G96R (on ENST00000357533 / NM_001366142.2; = p.G65R on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.31); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TTN | c.80941G>A p.E26981K (on ENST00000591111; = p.E19557K on NM_003319.4) | Missense Mutation (SNP) | VAF 69/209 reads (33%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.5588G>C p.R1863T (on ENST00000591111; = p.R1817T on NM_003319.4) | Missense Mutation (SNP) | VAF 182/444 reads (41%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBR5 | c.8126A>T p.Q2709L | Missense Mutation (SNP) | VAF 67/255 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- UGT1A10 | c.158A>G p.H53R | Missense Mutation (SNP) | VAF 75/282 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UNC80 | c.3686T>C p.V1229A | Missense Mutation (SNP) | VAF 105/337 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- UQCRC2 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- VCAM1 | c.518T>C p.L173P | Missense Mutation (SNP) | VAF 127/179 reads (71%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- VWC2L | c.208G>C p.G70R | Missense Mutation (SNP) | VAF 97/305 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR72 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 213/523 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- XIRP2 | c.5572G>C p.E1858Q (on ENST00000628543; = p.E2033Q on NM_152381.6) | Missense Mutation (SNP) | VAF 90/280 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- XIRP2 | c.8752C>A p.R2918S (on ENST00000628543; = p.R3093S on NM_152381.6) | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- XPR1 | c.31A>T p.I11F | Missense Mutation (SNP) | VAF 242/427 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- ZCCHC8 | c.1239G>T p.K413N | Missense Mutation (SNP) | VAF 150/486 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZEB2 | c.2824G>T p.G942* | Nonsense Mutation (SNP) | VAF 162/355 reads (46%) | called by muse, mutect2, varscan2
- ZFPM2 | c.3074C>A p.A1025D | Missense Mutation (SNP) | VAF 157/260 reads (60%) | SIFT tolerated (0.51); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF180 | c.892G>T p.G298* | Nonsense Mutation (SNP) | VAF 62/197 reads (31%) | called by muse, mutect2, varscan2
- ZNF337 | c.563A>T p.D188V | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ZNF714 | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 58/68 reads (85%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ZNF749 | c.791A>T p.K264M | Missense Mutation (SNP) | VAF 128/264 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ZNF786 | c.1834C>T p.Q612* | Nonsense Mutation (SNP) | VAF 58/107 reads (54%) | called by muse, mutect2, varscan2
- ZPBP2 | c.710C>A p.A237E (on ENST00000348931 / NM_199321.3; = p.A215E on NM_198844.3) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZZEF1 | c.4055A>G p.Y1352C | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.731); called by muse, mutect2
- ADAMTS20 | c.5625C>T p.V1875= | Silent (SNP) | VAF 69/142 reads (49%) | called by muse, mutect2, varscan2
- ADCY8 | c.2355G>T p.R785= | Silent (SNP) | VAF 112/541 reads (21%) | called by muse, mutect2, varscan2
- ANK2 | c.2112G>A p.Q704= | Silent (SNP) | VAF 186/455 reads (41%) | catalogued as rs998176656; called by muse, mutect2, varscan2
- APBB1 | c.1860G>T p.T620= | Silent (SNP) | VAF 72/179 reads (40%) | called by muse, mutect2, varscan2
- B3GAT1 | c.324G>A p.T108= | Silent (SNP) | VAF 72/160 reads (45%) | catalogued as rs759514133, COSV100438252; called by muse, mutect2, varscan2
- BEST3 | c.1044A>T p.T348= | Silent (SNP) | VAF 123/358 reads (34%) | catalogued as rs750334856; called by muse, mutect2, varscan2
- CABP1 | c.1017G>T p.V339= (on ENST00000316803 / NM_001033677.1; = p.V136= on NM_004276.5) | Silent (SNP) | VAF 91/209 reads (44%) | called by muse, mutect2, varscan2
- CALCRL | c.483C>A p.G161= | Silent (SNP) | VAF 47/142 reads (33%) | catalogued as rs539464823; called by muse, mutect2, varscan2
- CARS2 | c.474A>T p.P158= | Silent (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- CCDC144A | c.4284G>A p.*1428= | Silent (SNP) | VAF 60/443 reads (14%) | called by muse, mutect2, varscan2
- CDH23 | c.3381G>T p.T1127= | Silent (SNP) | VAF 109/318 reads (34%) | catalogued as rs752407400; called by muse, mutect2, varscan2
- CDH6 | c.1971C>A p.V657= | Silent (SNP) | VAF 107/253 reads (42%) | called by muse, mutect2, varscan2
- CHP1 | c.102G>T p.R34= | Silent (SNP) | VAF 45/119 reads (38%) | called by muse, mutect2, varscan2
- CHST3 | c.486C>T p.F162= | Silent (SNP) | VAF 174/408 reads (43%) | catalogued as rs774188997, COSV64150708; called by muse, mutect2, varscan2
- CNGB3 | c.465C>T p.L155= | Silent (SNP) | VAF 280/494 reads (57%) | called by muse, mutect2
- CPNE7 | c.1167C>T p.F389= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs1166853483; called by muse, mutect2, varscan2
- CPPED1 | c.402C>A p.P134= | Silent (SNP) | VAF 70/193 reads (36%) | catalogued as rs1405736375; called by muse, mutect2, varscan2
- CPPED1 | c.114C>T p.G38= | Silent (SNP) | VAF 92/235 reads (39%) | catalogued as rs556510257, COSV55501070; called by muse, mutect2, varscan2
- CSMD3 | c.7182G>A p.V2394= (on ENST00000297405 / NM_001363185.1; = p.V2290= on NM_052900.3) | Silent (SNP) | VAF 136/604 reads (23%) | catalogued as rs1234133046; called by muse, mutect2, varscan2
- DLG2 | c.2595C>A p.P865= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as COSV54688290; called by muse, mutect2, varscan2
- FBXL7 | c.297G>A p.P99= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs370682213; called by muse, mutect2, varscan2
- FN1 | c.4602T>C p.I1534= | Silent (SNP) | VAF 128/311 reads (41%) | called by muse, mutect2, varscan2
- GRM5 | c.1569C>A p.I523= | Silent (SNP) | VAF 50/94 reads (53%) | called by muse, mutect2, varscan2
- HS3ST4 | c.171C>A p.G57= | Silent (SNP) | VAF 47/123 reads (38%) | called by muse, mutect2, varscan2
- JMY | c.528G>A p.Q176= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as rs545856759; called by muse, mutect2, varscan2
- KCNH3 | c.2314C>A p.R772= | Silent (SNP) | VAF 33/53 reads (62%) | called by muse, mutect2, varscan2
- KCNQ5 | c.1533G>T p.V511= | Silent (SNP) | VAF 75/277 reads (27%) | called by muse, mutect2, varscan2
- KDM5A | c.3177G>A p.R1059= | Silent (SNP) | VAF 247/561 reads (44%) | called by muse, mutect2, varscan2
- KRTAP10-10 | c.258C>A p.T86= | Silent (SNP) | VAF 91/292 reads (31%) | called by muse, mutect2, varscan2
- KRTAP21-2 | c.174A>G p.G58= | Silent (SNP) | VAF 131/382 reads (34%) | called by muse, mutect2, varscan2
- LIPM | c.480T>A p.A160= | Silent (SNP) | VAF 85/171 reads (50%) | called by muse, mutect2, varscan2
- MAGEB2 | c.351G>A p.S117= | Silent (SNP) | VAF 96/118 reads (81%) | catalogued as rs944047855; called by muse, mutect2, varscan2
- MAGI2 | c.804C>A p.P268= | Silent (SNP) | VAF 121/314 reads (39%) | called by muse, mutect2, varscan2
- MALRD1 | c.5199A>T p.T1733= | Silent (SNP) | VAF 60/144 reads (42%) | catalogued as rs1432108231; called by muse, mutect2, varscan2
- MMEL1 | c.207G>A p.R69= | Silent (SNP) | VAF 54/74 reads (73%) | called by muse, mutect2, varscan2
- MROH9 | c.2583A>G p.L861= | Silent (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- MSX1 | c.465G>T p.P155= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as rs768687042; called by muse, mutect2, varscan2
- MUC16 | c.37698C>A p.S12566= | Silent (SNP) | VAF 145/176 reads (82%) | called by muse, mutect2, varscan2
- MXRA5 | c.1327C>A p.R443= | Silent (SNP) | VAF 112/132 reads (85%) | catalogued as COSV54245869; called by muse, mutect2, varscan2
- NIPA1 | c.495G>T p.L165= | Silent (SNP) | VAF 92/285 reads (32%) | called by muse, mutect2, varscan2
- OR10G9 | c.435C>A p.T145= | Silent (SNP) | VAF 82/203 reads (40%) | called by muse, mutect2, varscan2
- OR2T2 | c.102C>A p.S34= | Silent (SNP) | VAF 812/1929 reads (42%) | catalogued as COSV61618736; called by muse, mutect2, varscan2
- PDCL2 | c.51C>T p.F17= | Silent (SNP) | VAF 70/180 reads (39%) | catalogued as rs780180638, COSV55260095; called by muse, mutect2, varscan2
- PFKFB1 | c.1269C>T p.L423= | Silent (SNP) | VAF 94/110 reads (85%) | called by muse, mutect2, varscan2
- PJA1 | c.1662C>T p.H554= (on ENST00000361478 / NM_145119.4; = p.H366= on NM_022368.5) | Silent (SNP) | VAF 95/115 reads (83%) | called by muse, mutect2, varscan2
- PPARGC1B | c.2019C>T p.A673= | Silent (SNP) | VAF 39/109 reads (36%) | called by muse, mutect2, varscan2
- PRMT7 | c.645C>T p.D215= | Silent (SNP) | VAF 134/285 reads (47%) | catalogued as rs370445147; called by muse, mutect2, varscan2
- PRMT7 | c.1722C>G p.L574= | Silent (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- RAD50 | c.855T>C p.D285= | Silent (SNP) | VAF 167/368 reads (45%) | catalogued as rs1357279835; called by muse, mutect2, varscan2
- RYR2 | c.11031A>G p.T3677= | Silent (SNP) | VAF 113/134 reads (84%) | called by muse, mutect2, varscan2
- SLC6A20 | c.84G>T p.V28= | Silent (SNP) | VAF 66/99 reads (67%) | catalogued as COSV100653999; called by muse, mutect2, varscan2
- SLCO5A1 | c.960T>C p.G320= | Silent (SNP) | VAF 134/502 reads (27%) | called by muse, mutect2, varscan2
- SNCAIP | c.1557C>A p.A519= | Silent (SNP) | VAF 211/532 reads (40%) | called by muse, mutect2, varscan2
- STMN2 | c.81G>A p.P27= | Silent (SNP) | VAF 110/498 reads (22%) | catalogued as rs775608894, COSV55218379; called by muse, mutect2, varscan2
- SULT1B1 | c.333G>A p.P111= | Silent (SNP) | VAF 33/143 reads (23%) | catalogued as rs140573139; called by muse, mutect2, varscan2
- TAF1L | c.4917A>T p.T1639= | Silent (SNP) | VAF 118/162 reads (73%) | catalogued as rs142290416, COSV54256708; called by muse, varscan2
- TET1 | c.6090C>T p.T2030= | Silent (SNP) | VAF 79/165 reads (48%) | called by muse, mutect2, varscan2
- TMED3 | c.537C>A p.V179= | Silent (SNP) | VAF 66/172 reads (38%) | called by muse, mutect2, varscan2
- TNR | c.4057C>A p.R1353= | Silent (SNP) | VAF 45/155 reads (29%) | catalogued as COSV54914158; called by muse, mutect2, varscan2
- TNRC18 | c.213G>T p.V71= | Silent (SNP) | VAF 55/137 reads (40%) | called by muse, varscan2
- TRABD2B | c.570G>C p.L190= | Silent (SNP) | VAF 79/119 reads (66%) | called by muse, mutect2, varscan2
- TRPC3 | c.360C>A p.A120= (on ENST00000379645 / NM_001366479.2; = p.A47= on NM_003305.2) | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV53381882, COSV99312218; called by muse, mutect2, varscan2
- TTC23L | c.774C>T p.Y258= | Silent (SNP) | VAF 133/306 reads (43%) | catalogued as rs370183850; called by muse, mutect2, varscan2
- UGT2B4 | c.1545C>T p.V515= | Silent (SNP) | VAF 73/199 reads (37%) | catalogued as rs1321613830; called by muse, mutect2, varscan2
- VWA2 | c.1078C>T p.L360= | Silent (SNP) | VAF 48/109 reads (44%) | called by muse, mutect2, varscan2
- ZNF729 | c.984T>G p.T328= | Silent (SNP) | VAF 32/295 reads (11%) | called by muse, mutect2, varscan2
- ZNRF1 | c.382C>T p.L128= | Silent (SNP) | VAF 70/231 reads (30%) | catalogued as rs1240869791, COSV57727957; called by muse, mutect2, varscan2
- ZSCAN23 | c.822G>A p.E274= | Silent (SNP) | VAF 60/180 reads (33%) | catalogued as COSV57043716; called by muse, mutect2, varscan2
- ANO4 | c.-52C>T | 5'UTR (SNP) | VAF 67/224 reads (30%) | called by muse, mutect2, varscan2
- CBLB | c.2297-44G>T | Intron (SNP) | VAF 96/135 reads (71%) | called by muse, mutect2, varscan2
- CEP126 | c.507-1639C>G | Intron (SNP) | VAF 150/421 reads (36%) | called by muse, mutect2, varscan2
- CLEC7A | c.492+175G>T | Intron (SNP) | VAF 47/152 reads (31%) | called by muse, mutect2, varscan2
- CLEC7A | c.492+174G>T | Intron (SNP) | VAF 47/152 reads (31%) | called by muse, mutect2, varscan2
- DNM1P47 | n.539C>G | RNA (SNP) | VAF 49/204 reads (24%) | called by muse, varscan2
- DNM1P47 | n.592A>T | RNA (SNP) | VAF 97/362 reads (27%) | called by muse, varscan2
- GOLPH3L | c.183+499G>A | Intron (SNP) | VAF 30/47 reads (64%) | catalogued as rs1282907634; called by muse, mutect2, varscan2
- HNRNPA3P1 | n.340G>T | RNA (SNP) | VAF 43/109 reads (39%) | called by muse, mutect2, varscan2
- HTR2A | c.-485C>A | 5'UTR (SNP) | VAF 101/257 reads (39%) | catalogued as rs1269787834; called by muse, mutect2, varscan2
- IGFN1 | c.1242-1681C>A | Intron (SNP) | VAF 42/111 reads (38%) | called by muse, mutect2, varscan2
- KCNMB1 | c.306+70C>A | Intron (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- LMF1 | chr16:975830 C>A | 5'Flank (SNP) | VAF 85/153 reads (56%) | catalogued as rs1446890616; called by muse, mutect2, varscan2
- LYSMD3 | c.-93G>T | 5'UTR (SNP) | VAF 64/168 reads (38%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85434G>C | Intron (SNP) | VAF 175/455 reads (38%) | catalogued as COSV72279811; called by muse, mutect2, varscan2
- MGAM | c.4619-10067C>A | Intron (SNP) | VAF 105/309 reads (34%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92803C>G | Intron (SNP) | VAF 48/117 reads (41%) | called by muse, mutect2, varscan2
- OR3A4P | n.492C>T | RNA (SNP) | VAF 70/162 reads (43%) | catalogued as rs1167836825; called by muse, mutect2
- OR3A4P | n.952G>T | RNA (SNP) | VAF 132/290 reads (46%) | called by muse, mutect2, varscan2
- PEG10 | c.*772A>T | 3'UTR (SNP) | VAF 131/304 reads (43%) | called by muse, mutect2, varscan2
- PNPLA3 | c.*265C>T | 3'UTR (SNP) | VAF 80/193 reads (41%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2344+5800C>T | Intron (SNP) | VAF 88/213 reads (41%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159852 G>T | 5'Flank (SNP) | VAF 20/61 reads (33%) | called by muse, varscan2
- RPS13 | c.23+68G>T | Intron (SNP) | VAF 21/95 reads (22%) | catalogued as rs966349132; called by muse, mutect2, varscan2
- RUFY2 | c.-223G>C | 5'UTR (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- SCN3A | c.3967-32G>T | Intron (SNP) | VAF 118/318 reads (37%) | catalogued as rs755657861; called by muse, mutect2, varscan2
- SOX8 | chr16:976897 C>T | 5'Flank (SNP) | VAF 61/206 reads (30%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-3622C>A | Intron (SNP) | VAF 48/146 reads (33%) | called by muse, mutect2, varscan2
- SRP19 | c.*65G>A | 3'UTR (SNP) | VAF 115/284 reads (40%) | called by muse, mutect2, varscan2
- SUMO1 | c.238-678C>T | Intron (SNP) | VAF 8/19 reads (42%) | catalogued as rs904136289; called by muse, mutect2, varscan2
- UBBP4 | n.881G>A | RNA (SNP) | VAF 136/340 reads (40%) | catalogued as rs763745114; called by muse, varscan2
- UCHL3 | c.-9A>C | 5'UTR (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- VAPB | c.*2471del | 3'UTR (DEL) | VAF 47/149 reads (32%) | called by mutect2, pindel, varscan2
- ZNF680 | c.254-4003G>T | Intron (SNP) | VAF 38/105 reads (36%) | called by muse, mutect2, varscan2
